Somatic mutation profile of tumor specimen PCProject_0439_T2_WES (aliquot PCProject_0439_T2_WES_1) from CMI case PCProject_0439, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.9 years (24,443 days).
Specimen PCProject_0439_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef7bca1f-01f7-4143-a2d0-a753f1ab47aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0439_SALIVA (DNA), aliquot PCProject_0439_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50e979cf-d560-41b0-9982-2b87ac1739d0

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Intron 3, Frame Shift Del 2, 3'UTR 1, Splice Site 1, Splice Region 1, In Frame Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3460C>T p.R1154W | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs387907208, CM124860, COSV53963892; ClinVar: pathogenic; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.6529G>A p.V2177M | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.556); catalogued as rs773298197, COSV51842683; called by muse, mutect2, varscan2
- ANKRD65 | c.709del p.A237Pfs*10 | Frame Shift Del (DEL) | VAF 3/21 reads (14%) | catalogued as rs1408184135; called by pindel, varscan2
- DEAF1 | c.63_80del p.V25_A30del | In Frame Del (DEL) | VAF 24/63 reads (38%) | catalogued as rs1461468531; called by mutect2, varscan2
- FAM205A | c.3889G>A p.D1297N | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs532422895, COSV66488667; called by muse, mutect2, varscan2
- FBN2 | c.2965G>T p.D989Y | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52549545; called by muse, mutect2, varscan2
- GPR174 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.105); catalogued as rs1489127095, COSV52133424; called by muse, mutect2
- ODF3L1 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs568456859, COSV59820565; called by muse, mutect2, varscan2
- OR2A2 | c.855C>A p.N285K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as rs150058768, COSV68872182; called by muse, mutect2, varscan2
- UGT2A1 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.05); catalogued as rs969552482, COSV54139225; called by muse, mutect2, varscan2
- ABCC1 | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- ATF2 | c.332T>C p.L111S | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.535); called by muse, mutect2
- CD55 | c.284_286+5del p.X95_splice | Splice Site (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- CDKN1B | c.174dup p.K59Qfs*66 | Frame Shift Ins (INS) | VAF 93/414 reads (22%) | called by mutect2, pindel, varscan2
- CLN3 | c.784G>T p.V262F (on ENST00000360019 / NM_001286104.2; = p.V286F on NM_000086.2) | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2
- MUC16 | c.3188C>T p.A1063V | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYD88 | c.329-5C>T | Splice Region (SNP) | VAF 51/162 reads (31%) | called by muse, mutect2, varscan2
- NUP35 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PBX1 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- RBM10 | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THEM6 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMYM3 | c.1592_1593del p.S531Lfs*24 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- CFHR5 | c.1116C>T p.N372= | Silent (SNP) | VAF 56/223 reads (25%) | catalogued as rs556270179, COSV56829596; called by muse, mutect2, varscan2
- G2E3 | c.1725T>C p.Y575= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV52838678; called by muse, mutect2
- GABRG1 | c.1080C>T p.N360= | Silent (SNP) | VAF 33/177 reads (19%) | called by muse, mutect2, varscan2
- GRIN2B | c.3813G>A p.A1271= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as rs201906121; called by muse, mutect2, varscan2
- KAT2B | c.459G>A p.V153= | Silent (SNP) | VAF 11/119 reads (9%) | called by muse, mutect2
- ZSCAN20 | c.2895A>G p.G965= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs770352547; called by muse, mutect2, varscan2
- AC098650.1 | c.*115+15993_*115+15998delinsTAGACAAT | Intron (INS) | VAF 4/50 reads (8%) | called by pindel, varscan2*
- OBSCN | c.19767+9G>A | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, varscan2
- PTGES3 | c.2+48_2+52dup | Intron (INS) | VAF 28/100 reads (28%) | called by mutect2, pindel, varscan2
- TCEANC2 | c.*8199A>G | 3'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as rs1356049508; called by muse, varscan2
